Somatic mutation profile of tumor specimen TCGA-VR-AA4D-01A (aliquot TCGA-VR-AA4D-01A-11D-A37C-09) from TCGA case TCGA-VR-AA4D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.0 years (19,714 days).
Specimen TCGA-VR-AA4D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58f66fc7-9c2b-4d12-9bb9-f67074eaf8e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-AA4D-10A (Blood Derived Normal), aliquot TCGA-VR-AA4D-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19886e80-413e-42c7-891e-395fca64b7b3

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 25, Frame Shift Ins 5, Frame Shift Del 4, Nonsense Mutation 3, In Frame Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APEH | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs374901664; called by muse, mutect2, varscan2
- ARID4B | c.3787C>T p.R1263C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183357307; called by muse, mutect2
- ASMT | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.235); catalogued as rs201053197; called by muse, mutect2, varscan2
- BRINP3 | c.2093C>A p.S698* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV66518458; called by muse, mutect2, varscan2
- C12orf4 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866573238, COSV99712667; called by muse, mutect2, varscan2
- C2CD3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs868548121; called by muse, mutect2, varscan2
- CCR9 | c.784G>A p.V262I (on ENST00000357632 / NM_031200.3; = p.V250I on NM_006641.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs202070482; called by muse, mutect2, varscan2
- CSF1R | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); catalogued as rs1432099970, COSV53832574; called by muse, mutect2
- CSMD3 | c.10246A>C p.T3416P (on ENST00000297405 / NM_001363185.1; = p.T3247P on NM_052900.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV52261909; called by muse, mutect2, varscan2
- FAM124A | c.869G>A p.G290D (on ENST00000322475 / NM_001242312.2; = p.G326D on NM_145019.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV54476525; called by muse, mutect2, varscan2
- FRMD5 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as rs371288449; called by muse, mutect2, varscan2
- GABRB3 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767913731, COSV100160264, COSV54661676; called by muse, mutect2, varscan2
- IRF2BP2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1459243343; called by muse, mutect2, varscan2
- MEFV | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs144998416; called by muse, mutect2, varscan2
- MEGF6 | c.3670G>A p.G1224R | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as rs865833922; called by muse, mutect2, varscan2
- MRPL16 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs768391952; called by muse, mutect2, varscan2
- MYCBP2 | c.6314T>C p.I2105T (on ENST00000357337; = p.I2143T on NM_015057.5) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs373012467; called by muse, mutect2, varscan2
- NAPSA | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs757907641; called by muse, mutect2, varscan2
- NEMP1 | c.911C>T p.A304V (on ENST00000300128 / NM_001130963.2; = p.A231V on NM_015257.3) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV55662052; called by muse, mutect2, varscan2
- NFATC4 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324725522; called by muse, mutect2, varscan2
- NUMA1 | c.5341C>T p.R1781W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs529393250, COSV52621748; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2, varscan2
- OR6B2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as rs765870233, COSV99401827; called by muse, mutect2, varscan2
- PCDHA10 | c.824A>T p.E275V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV56516960; called by muse, mutect2, varscan2
- PRDM10 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948779519; called by muse, mutect2, varscan2
- SAMD9L | c.2494dup p.T832Nfs*16 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as rs1344505157; called by mutect2, pindel, varscan2
- SPAG17 | c.4822T>A p.L1608M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1489040160, COSV100308356; called by muse, mutect2, varscan2
- SPATA31D1 | c.3357A>C p.Q1119H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100782379; called by muse, mutect2, varscan2
- STAB2 | c.4646A>G p.D1549G | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1177127798; called by muse, mutect2, varscan2
- SYNPO | c.2575C>T p.R859W (on ENST00000394243 / NM_001166208.2; = p.R615W on NM_007286.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781217685; called by muse, mutect2, varscan2
- TBX19 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs765043625; called by muse, mutect2, varscan2
- TCTEX1D4 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs960243440; called by muse, mutect2, varscan2
- TRPM3 | c.2515C>T p.R839* (on ENST00000357533 / NM_001366142.2; = p.R682* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as rs777039638, CM142979, COSV62581909; called by muse, mutect2, varscan2
- TSHZ3 | c.2510C>G p.S837W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53682964; called by muse, mutect2, varscan2
- WNT7B | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1325810783; called by muse, mutect2, varscan2
- ZNF668 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs774253924; called by muse, mutect2
- AC013477.1 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACVR2B | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASIC5 | c.142del p.H48Mfs*29 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ATP23 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- BRI3 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BTN3A1 | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- BTN3A2 | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAND2 | c.2446C>T p.P816S (on ENST00000456430 / NM_001162499.2; = p.P723S on NM_012298.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CDK10 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CLEC18B | c.33dup p.H12Afs*57 | Frame Shift Ins (INS) | VAF 38/149 reads (26%) | called by mutect2, pindel, varscan2
- CSMD2 | c.5981G>T p.C1994F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRID2 | c.1054A>C p.S352R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- GTDC1 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXC4 | c.75_97del p.N26Sfs*28 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- KAT2B | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- KLHL23 | c.829A>T p.I277L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KLK12 | c.633A>T p.Q211H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LAMC1 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LPIN3 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAN2B1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MBTD1 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MINAR1 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- MRC2 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- MTSS1 | c.134+1G>A p.X45_splice | Splice Site (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- NKX2-4 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- OR10A4 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OTC | c.677A>T p.D226V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PCDHA8 | c.1286_1290dup p.G431Tfs*20 | Frame Shift Ins (INS) | VAF 36/55 reads (65%) | called by mutect2, varscan2
- PCDHB10 | c.2144_2148dup p.R717Cfs*27 | Frame Shift Ins (INS) | VAF 38/56 reads (68%) | called by mutect2, varscan2
- PCDHB9 | c.2138_2142dup p.R715Cfs*27 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | called by mutect2, varscan2
- PCDHGA6 | c.1705A>T p.T569S | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PIK3R1 | c.99_101dup p.N33dup | In Frame Ins (INS) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- PLIN3 | c.1236_1237del p.P413Cfs*14 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by pindel, varscan2
- PRAMEF5 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RNF165 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SCNM1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SLC35B3 | c.599_635del p.V200Gfs*15 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel
- TMPRSS11B | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TNS1 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPV2 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ACVR1 | c.1188C>T p.F396= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs774558962, COSV55118445, COSV55121277; called by muse, mutect2, varscan2
- ADORA1 | c.507C>T p.C169= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs753000079, COSV55141980; called by muse, mutect2, varscan2
- AOX1 | c.1041C>T p.S347= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV101022132; called by muse, mutect2, varscan2
- FAT3 | c.10017C>A p.P3339= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- FPR1 | c.279C>T p.F93= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs374349320, COSV59051119; called by muse, mutect2, varscan2
- GRIN2A | c.1986G>A p.V662= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1435276408; called by muse, mutect2, varscan2
- HECTD4 | c.3540C>A p.R1180= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV61179259; called by muse, mutect2, varscan2
- IGF2R | c.6867C>T p.P2289= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs149900660; called by muse, mutect2, varscan2
- IL22RA1 | c.1695C>A p.G565= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- KRTAP1-5 | c.468G>A p.P156= | Silent (SNP) | VAF 25/758 reads (3%) | catalogued as rs534171351, COSV62624057; called by muse, mutect2
- KRTAP10-5 | c.21C>T p.S7= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs1285941923; called by muse, mutect2, varscan2
- NPFFR1 | c.900G>A p.A300= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- ODF3L2 | c.675G>T p.L225= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- OR10K1 | c.619T>C p.L207= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- PACS1 | c.2304C>T p.D768= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV57698507; called by muse, mutect2, varscan2
- PDZRN3 | c.1116G>A p.K372= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- POLD2 | c.1038A>T p.G346= | Silent (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- SASH1 | c.510A>C p.S170= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, varscan2
- SCN9A | c.4257T>C p.V1419= (on ENST00000303354; = p.V1408= on NM_002977.3) | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- STAT3 | c.465G>T p.V155= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- TMEM67 | c.780C>T p.Y260= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs966581270, COSV60044284; called by muse, mutect2, varscan2
- TNR | c.819G>A p.K273= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV54899447; called by muse, mutect2, varscan2
- UGT1A3 | c.459C>T p.P153= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs138617806, COSV59390747; called by muse, mutect2, varscan2
- ZNF615 | c.1329C>A p.L443= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV65033541; called by muse, mutect2, varscan2
- ZNF804A | c.3048T>C p.T1016= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- IZUMO4 | c.370+176C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs776673193; called by muse, mutect2, varscan2
